Surgical pathology report (de-identified scan), TCGA case TCGA-BS-A0TC, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii, specimen TCGA-BS-A0TC-01A (Primary Tumor).

[page 1 of 2]
Diagnostic Discrepancy		

Surgical Pathology Report

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED]
DOB: [REDACTED]
Gender: F
Physician(s): [REDACTED]
cc: [REDACTED]

Client: [REDACTED]
Location: [REDACTED]

Accession #: [REDACTED]
Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

History/Clinical Dx: Endometrial cancer

Postoperative Dx: Same, pending pathology examination

Specimen(s) Received:

- A: Uterus, cervix, tubes and ovaries
- B: Left pelvic lymph nodes
- C: Left aortic lymph nodes
- D: Right pelvic lymph nodes
- E: Right caval lymph nodes

100-0-3
adeno. carcinoma, endometrioid, NOS 8380/3
Path Site: endometrium c54.1 w 10/27/11
CQCF : fundus uteri c54.3

DIAGNOSIS:

A. Uterus, cervix, tubes and ovaries:

ENDOMETRIAL ADENOCARCINOMA

Tumor Information:

Operative procedure:	TAH-BSO with node sampling
Histologic type:	Endometrioid
Histologic grade(FIGO):	Grade 1
Nuclear grade:	2
Tumor size:	2.4 x 2.0 x 1.8 cm
Extent of invasion:	Less than 50% (2 mm of invasion)
Lympho/vascular invasion:	Not identified
Serosa:	Free of tumor
Parametrium:	Free of tumor
Cervical involvement:	Absent
Right adnexa:	No evidence of tumor
Left adnexa:	No evidence of tumor
Staging Information:	T1b, N0

- | | |
|------------------------------|---|
| B. Left pelvic lymph nodes: | Eleven lymph nodes negative for metastasis (0/11) |
| C. Left aortic lymph nodes: | Three lymph nodes negative for metastasis (0/3) |
| D. Right pelvic lymph nodes: | Nine lymph nodes negative for metastasis (0/9) |

Regulatory Statement:

The following statement may be applicable to some of the reagents/antibodies used in developing the above report: This test was developed and its performance characteristics determined by [REDACTED] and approved by the U.S. Food and Drug Administration. The FDA has determined that such elements are approved for use. This test is used for clinical purposes, which may not be subject to the same regulatory requirements as research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 2 of 2]
Surgical Pathology Report

E. Right caval lymph nodes:

Two lymph nodes negative for metastasis (0/2)

Gross Description

- A. Submitted as "uterus, cervix, bilateral ovaries and tubes" is a uterus with attached cervix and bilateral tubes and ovaries weighing 138 gms. It measures 7.8 x 5.2 x 5.0 cm in greatest dimension. It has been bivalved. The ectocervical mucosa is smooth, the endocervical canal contains a smooth polyp which measures 1.2 cm. The endometrial cavity contains a polypoid tan-gray mass within the uterine fundus. It measures approximately 2.4 x 2.0 x 1.8 cm in greatest dimension. Sectioning through the mass shows equivocal early myometrial invasion. The myometrium measures approximately 2.2 cm in thickness. The right tube measures 4.0 cm length and up to 0.4 cm in diameter. There is a paratubal cyst measuring 0.5. The right ovary measures 2.0 x 0.9 x 0.5 cm in greatest dimension and is grossly unremarkable. The left tube measures 2.9 cm in length by up to 0.5 cm in diameter. The left ovary reveals 2.3 x 1.1 x 0.6 cm and is grossly unremarkable.

KEY TO CASSETTES

A1	-	Cervix and endocervical polyp
A2	-	Lower uterine segment
A3-A9	-	Endometrial tumor and underlying myometrium
A10	-	Parametrium
A11	-	Right tube and ovary
A12	-	Left tube and ovary

- B. Submitted as "left pelvic lymph nodes" show 4 fragments of fat tissue weighing 10.0 gms in aggregate. The nodes are removed and submitted intact in four cassettes.
- C. Submitted as "left aortic lymph nodes" are three fragments of fibrofatty tissue weighing 5 grams in aggregate. The nodes are removed and submitted intact for one cassette.
- D. Submitted as "right pelvic lymph nodes" are multiple fragments of hemorrhagic fatty tissue weighing 20 gms in aggregate. The lymph nodes are removed and submitted intact in four cassettes.
- E. Submitted as "right caval node" is a single fragment of fatty tissue weighing 3 grams. There is a firm node measuring approximately 1.8 cm. The entire specimen is submitted in two cassettes with the node bisected and submitted in cassette E1.

Microscopic Description

The microscopic findings support the above diagnosis.

Source: NCI Genomic Data Commons file e4b52142-e758-4408-b763-931190a47b1b (TCGA-BS-A0TC.8AA64402-A062-410D-85B8-24DAD320916D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).